Somatic mutation profile of tumor specimen TCGA-DU-A6S2-01A (aliquot TCGA-DU-A6S2-01A-21D-A32B-08) from TCGA case TCGA-DU-A6S2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.2 years (13,597 days).
Specimen TCGA-DU-A6S2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed776e71-65e6-464d-837f-d061e5b0f0a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A6S2-10A (Blood Derived Normal), aliquot TCGA-DU-A6S2-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94beff1e-1434-413c-9bd4-c9bef58e4733

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50579323, COSV50627795; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKLE2 | c.1190G>A p.R397H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs376116293; called by muse, mutect2, varscan2
- FUBP1 | c.779_780insCT p.R262Sfs*12 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | catalogued as COSV99629480; called by mutect2, pindel, varscan2
- GATB | c.22T>A p.W8R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99859271; called by muse, mutect2, varscan2
- LIMCH1 | c.2849C>T p.T950M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs147660035; called by muse, mutect2, varscan2
- OR2A25 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs374373324, COSV68716883, COSV68717463; called by muse, mutect2, varscan2
- PTCHD1 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV101037964; called by muse, mutect2, varscan2
- PTPRZ1 | c.5123T>C p.V1708A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66440709; called by muse, mutect2, varscan2
- RPS6KA5 | c.2365A>G p.N789D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1266646054, COSV100003087; called by muse, mutect2, varscan2
- THEG | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as COSV100700643; called by muse, mutect2, varscan2
- TMEM95 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99341922; called by muse, mutect2, varscan2
- ABCA9 | c.1782G>A p.V594= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100383410; called by muse, varscan2
- IBSP | c.351C>T p.D117= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs779776336, COSV56896798; called by muse, mutect2, varscan2
- LHX2 | c.552C>T p.A184= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs764880708, COSV101010084; called by muse, mutect2
- ZBTB45 | c.531G>A p.A177= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1179223220, COSV63524441; called by muse, mutect2, varscan2
